Gene-level copy-number profile of tumor specimen ALCH-AEBL-TTP1-A from ALCHEMIST case ALCH-AEBL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.6 years (27,627 days).
Specimen ALCH-AEBL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d06aaeac-451e-4ac2-8c8d-407e6d74188b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEBL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,737 have no estimate.
https://portal.gdc.cancer.gov/files/2742c306-f951-486c-879e-1f68ae042285

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 7,011; copy number 2: 47,678; copy number 3: 4,106; copy number 4: 11; copy number 5: 3; copy number 6: 13; copy number 7: 6; copy number 9: 6; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,926,162–12,928,253, 1 gene (within-gene range 0–2): PRAMEF29P.
- chr1:37,953,508–37,953,780, 1 gene: Metazoa_SRP.
- chr2:42,511,570–42,511,851, 1 gene (within-gene range 0–2): Metazoa_SRP.
- chr3:10,081,317–10,108,255, 1 gene (within-gene range 0–2): FANCD2OS.
- chr3:57,548,838–57,548,945, 1 gene: RNU6-483P.
- chr5:176,556,704–176,556,805, 1 gene (within-gene range 0–2): Y_RNA.
- chr10:33,034,655–33,035,664, 2 genes (within-gene range 0–2): RN7SL847P, AL365203.1.
- chr11:65,040,901–65,058,553, 2 genes: SAC3D1, NAALADL1.
- chr16:668,105–674,174, 1 gene (within-gene range 0–2): RHOT2.
- chr17:67,044,554–67,056,797, 1 gene: CACNG1.
- chr17:75,897,060–75,905,093, 2 genes: AC087289.2, MRPL38.
- chr18:59,081,911–59,085,920, 1 gene: AC040963.1.
- chr19:6,928,345–6,928,629, 1 gene (within-gene range 0–2): Metazoa_SRP.
- chr19:19,264,364–19,273,391, 1 gene: TM6SF2.
- chr19:37,024,886–37,025,254, 1 gene (within-gene range 0–2): AC010632.3.
- chr19:49,361,783–49,375,116, 1 gene (within-gene range 0–2): DKKL1.
- chr21:45,981,769–46,005,050, 1 gene: COL6A1.
- chr22:21,417,371–21,451,463, 1 gene: HIC2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 29 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:189,703,881–189,704,490, 1 gene, copy number 5: AF250324.1.
- chr7:73,861,159–73,865,890, 1 gene, copy number 7: TMEM270.
- chr9:64,637,845–64,709,311, 2 genes, copy number 5: AL445665.1, BMS1P11.
- chr11:1,991,096–2,001,470, 5 genes, copy number 9–26: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr16:153,892–173,710, 4 genes, copy number 6–9 (within-gene range 2–9): HBM, HBZP1, HBAP1, HBA2.
- chr16:629,239–649,200, 4 genes, copy number 6–7 (within-gene range 2–7): WFIKKN1, METTL26, MCRIP2, AL022341.1.
- chr16:29,806,106–29,822,489, 7 genes, copy number 6 (within-gene range 2–6): MAZ, AC009133.2, AC009133.1, AC009133.5, PRRT2, AC009133.6, PAGR1.
- chr22:18,422,244–18,524,935, 5 genes, copy number 6–7: FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 4,373. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
